FM case AD16010 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/b8b761ba-a865-420c-b145-ef64a810272b

Male, 66.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
